Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7649, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7649-01A (Primary Tumor).

[page 1 of 3]
ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder
- B. Node of importance
- C. Bile duct margin - fs
- D. Duodenum, pancreatic margin (long stitch), uncinate margin (short stitch)

CLINICAL HISTORY:

ERCP shows common bile duct and pancreatic duct stricture - brushings show high grade epithelial neoplasia.

DIAGNOSIS:

- A. GALLBLADDER, CHOLECYSTECTOMY:
- ACUTE CHOLECYSTITIS AND CHOLELITHIASIS.
- NEGATIVE FOR DYSPLASIA OR MALIGNANCY.
- B. NODE OF IMPORTANCE, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- LYMPH NODE WITH LIPID GRANULOMAS.
- C. BILE DUCT MARGIN, EXCISION:
- NEGATIVE FOR MALIGNANCY.
- MIXED ACUTE AND CHRONIC INFLAMMATION.
- D. DUODENUM AND PORTION OF PANCREAS, PANCREATODUODENECTOMY (WHIPPLE PROCEDURE):
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA OF PANCREATIC HEAD (SEE COMMENT).
- TUMOR SIZE: 3.0 X 4.0 X 2.5 CM.
- INFILTRATING INTO DUODENAL WALL AND COMMON BILE DUCT.
- LYMPHOVASCULAR INVASION PRESENT.
- PERINEURAL INVASION PRESENT.
- TUMOR IS PRESENT AT THE TRIMMED UNCINATE MARGIN.
- DUODENAL MARGINS, PANCREATIC MARGIN, AND COMMON BILE DUCT MARGIN FREE OF TUMOR.
- FIVE OF THIRTEEN (5/13) LYMPH NODES POSITIVE FOR METASTASIS.

FINAL

[page 2 of 3]
DIAGNOSIS:

Reported by:
Signed by:

GROSS DESCRIPTION:

A. Received fresh is a 10 x 3.5 x 2 cm gallbladder. The serosal surface is smooth and shiny. A roughened area is corresponding to area attached to the liver. On opening, the gallbladder is filled with multiple dark brown stones, measuring from 0.5 to 1.5 cm in size and 5 x 3 x 1.5 cm in aggregate. The mucosal surface is trabecular and appears flattened. The wall thickness measures 0.4 cm. Two representative sections are submitted in one cassette. [REDACTED]

B. Received in formalin is a 1.5 x 1 x 0.5 cm lymph node. The node is bisected and entirely submitted in one cassette. [REDACTED]

C. Irregular fragment of soft tissue measuring 0.6 x 0.3 x 0.2 cm, submitted in toto for FS. [REDACTED]

The tissue used for frozen section is resubmitted in cassette CQS. [REDACTED]

D. Received in fresh state is a Whipple resection containing a portion of duodenum, common bile duct and portion of pancreas. The long stitch labels the pancreatic margin and the short stitch labels the uncinate margin. The duodenum measures 24 cm in length and 5.7 cm in circumference. The portion of pancreas measures 2.5 cm in length and 6 x 4.5 cm on cut surface. There is a mesh stent in the common bile duct. The common bile duct measures 6 cm in length with a diameter of 1.3 cm. Cross sections of the pancreatic tissue reveal a 3 x 4 x 2.5 cm tan-yellow firm mass which is grossly invading into the duodenal wall and common bile ductal wall. Representative sections are submitted as follows:

- D1 - proximal duodenal margin.
- D2 - distal duodenal margin.
- D3 - pancreatic margin.
- D4 - uncinate margin.
- D5 - common bile duct margin.
- D6, D7 - common bile duct with underlying pancreatic tumor.
- D8, D9 - common bile duct, duodenum and underlying tumor.
- D10 - common bile duct.

FINAL

[page 3 of 3]
PATHOLOGY REPORT

Inquiry Number:

Division Head:

GROSS DESCRIPTION:

- D11, D12 - one tumor cut section including adjacent normal pancreatic tissue.
D13 - another tumor section.

Please note the pancreatic margin and uncinate margin are trimmed and the common bile duct margin is also a trimmed margin. Also attached to the specimen is a 5 x 4 x 2 cm piece of adipose tissue. There are several white tan lymph nodes identified and entirely submitted in cassette D14. [REDACTED]

FROZEN SECTION DIAGNOSIS:

C. BILE DUCT MARGIN:

- NEGATIVE FOR MALIGNANCY
[REDACTED]

COMMENT:

The main tumor mass is in the pancreatic head. However, the duodenal wall and common bile duct are also infiltrated. Morphologically the tumor is either from pancreatic duct or from bile duct. The pathological stage is IIB (PT3, N1).

[REDACTED]

FINAL

[REDACTED]

Source: NCI Genomic Data Commons file d1ed7d5b-d014-4693-8669-9969f27f7620 (TCGA-IB-7649.FC689C64-8C88-492C-AC93-866AD0C243DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).